Somatic mutation profile of tumor specimen TARGET-10-PAPFNV-09A (aliquot TARGET-10-PAPFNV-09A-01D) from TARGET case TARGET-10-PAPFNV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,654 days).
Specimen TARGET-10-PAPFNV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d05191e0-1210-4f93-b946-ff9c2a077a59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPFNV-14A (Bone Marrow Normal), aliquot TARGET-10-PAPFNV-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8546cd6a-64cc-4105-a2d1-89275bf6a87d

The open-access MAF lists 46 somatic variants for this specimen: 34 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 8, Nonsense Mutation 3, 5'UTR 3, Translation Start Site 1, Splice Site 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 12/96 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AIFM3 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs367600638; called by muse, mutect2, varscan2
- ATP12A | c.1349C>G p.P450R | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.773); catalogued as COSV99517346; called by muse, mutect2, varscan2
- EFCAB14 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64238366, COSV64240023; called by muse, mutect2, varscan2
- GALNT16 | c.1315G>A p.V439M | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.269); catalogued as rs1452277824; called by muse, mutect2, varscan2
- GRWD1 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1006520417; called by muse, mutect2
- NLGN1 | c.1997C>T p.S666L | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV64328033; called by muse, mutect2
- OR1M1 | c.447G>C p.W149C | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV70037118; called by muse, mutect2
- OR2T6 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.376); catalogued as rs750710520, COSV63215692; called by muse, mutect2, varscan2
- PTPRT | c.3769G>A p.V1257M | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.199); catalogued as rs375402843; called by muse, mutect2, varscan2
- RBM33 | c.3400C>T p.R1134W | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62030933; called by muse, mutect2, varscan2
- SETD2 | c.208C>T p.R70* | Nonsense Mutation (SNP) | VAF 31/159 reads (19%) | catalogued as rs775039657, COSV57442704; called by muse, mutect2, varscan2
- SHKBP1 | c.1261C>T p.Q421* | Nonsense Mutation (SNP) | VAF 22/69 reads (32%) | catalogued as rs962708642; called by muse, mutect2, varscan2
- SLC12A4 | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as rs376059966; called by muse, mutect2, varscan2
- SLC7A2 | c.1582G>A p.A528T (on ENST00000494857 / NM_001370338.1; = p.A567T on NM_003046.6) | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as rs144968267; called by muse, mutect2, varscan2
- ZNF462 | c.4789G>A p.E1597K | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs151086190; called by muse, mutect2, varscan2
- ARHGAP36 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- BUB1B | c.2956G>A p.E986K | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT tolerated (0.91); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C11orf65 | c.584C>G p.A195G | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CEP68 | c.1816G>C p.D606H | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL4A4 | c.5056T>A p.C1686S | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ETV6 | c.919dup p.S307Ffs*20 | Frame Shift Ins (INS) | VAF 13/72 reads (18%) | called by mutect2, pindel, varscan2
- FAM181B | c.1075G>C p.D359H | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- FBXO10 | c.2207G>C p.G736A | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXO27 | c.821C>G p.S274C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- IGHV3-20 | c.348_353delinsTTAGAC p.R117* | Nonsense Mutation (ONP) | VAF 34/115 reads (30%) | called by pindel, varscan2*
- KCTD10 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- LZTFL1 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, varscan2
- MYO1H | c.1457T>C p.L486P | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PNLIPRP1 | c.103G>T p.G35C | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SIM1 | c.2086C>T p.P696S | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UBR4 | c.8576C>G p.S2859C | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- USP47 | c.2912T>C p.L971S (on ENST00000399455 / NM_001372095.1; = p.L883S on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 115/285 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- VEGFC | c.552+1G>A p.X184_splice | Splice Site (SNP) | VAF 13/71 reads (18%) | called by muse, mutect2, varscan2
- APOF | c.723C>T p.I241= | Silent (SNP) | VAF 27/143 reads (19%) | called by muse, mutect2, varscan2
- ATG13 | c.1164G>A p.T388= (on ENST00000359513 / NM_001346321.1; = p.T351= on NM_014741.4 and 9 other RefSeq transcripts) | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as rs778394445, COSV100365748; called by muse, mutect2, varscan2
- COL4A4 | c.5055C>T p.V1685= | Silent (SNP) | VAF 38/156 reads (24%) | called by muse, mutect2, varscan2
- MGAM | c.1038C>T p.L346= | Silent (SNP) | VAF 35/183 reads (19%) | catalogued as rs368638022, COSV72074535; called by muse, mutect2, varscan2
- NID2 | c.2373G>T p.G791= | Silent (SNP) | VAF 17/67 reads (25%) | called by muse, mutect2, varscan2
- OLFM1 | c.1080C>T p.D360= (on ENST00000371793 / NM_001282611.2; = p.D342= on NM_014279.5) | Silent (SNP) | VAF 22/127 reads (17%) | catalogued as rs747535964, COSV99422922; called by muse, mutect2, varscan2
- SMS | c.132C>T p.D44= | Silent (SNP) | VAF 8/37 reads (22%) | called by muse, varscan2
- ZNF136 | c.1380C>G p.L460= | Silent (SNP) | VAF 17/111 reads (15%) | called by muse, mutect2, varscan2
- EOLA1 | c.-141C>A | 5'UTR (SNP) | VAF 6/81 reads (7%) | called by muse, mutect2
- NFKBID | c.-34G>A | 5'UTR (SNP) | VAF 17/70 reads (24%) | catalogued as rs767702552; called by muse, mutect2, varscan2
- PISD | c.-44C>T | 5'UTR (SNP) | VAF 22/146 reads (15%) | called by muse, mutect2, varscan2
- ZNF136 | c.*5C>G | 3'UTR (SNP) | VAF 29/162 reads (18%) | called by muse, mutect2, varscan2
